Surgical pathology report (de-identified scan), TCGA case TCGA-62-A471, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A471-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, left, upper lobe: 23.0 x 16.0 x 8.0 cm

tumor: 6.5 x 6.5 x 5.0 cm

Diagnosis:

Adenocarcinoma (NOS)

No Infiltration of pleura visceralis

pT2b, pN1 (6/28), pMx, G3

Supplementary examinations:

IHC:

tumor cells positive for CK7

tumor cells negative for: CK5/6, CK14, SP-A, TTF1

tumor cells negative for: CD56, Chromogranin A, Synaptophysin

Ki-67: 40%

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: lung, upper lobe c34.1

hw
9/24/12

Pathologist:

IHPAA Discrepancy		☒

hw
8/24/12

Source: NCI Genomic Data Commons file 986c5a54-1515-4e4c-883f-756c83615926 (TCGA-62-A471.5F2495BD-2398-4C97-8F3E-76E979F22691.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).